TARGET case TARGET-30-PAPRXW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fc3288a3-ad98-5be3-ab70-e02bf4b8fc7c

Demographics
Sex at birth: male; Race: white; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 2.4 years (888 days); Year of diagnosis: 2006; Days to last follow up: 3,894 days (10.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 20; Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,894 days (10.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,894; Year of follow up: 2017.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPRXW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPRXW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3894
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 60/40
